CCDI case PBCBTJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Bones, joints and articular cartilage of other and unspecified sites.
https://portal.gdc.cancer.gov/cases/892fb331-74fe-4f5f-8ee6-cee828929e64

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Spindle cell sarcoma: ICD-O-3 morphology code: 8801/3; Tissue or organ of origin: Head, face or neck, NOS; Age at diagnosis: 20.3 years (7,425 days).

Biospecimens (2 samples)
- Sample 0DOXFY: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DOXH1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
